Somatic mutation profile of tumor specimen TCGA-VM-A8CF-01A (aliquot TCGA-VM-A8CF-01A-11D-A36O-08) from TCGA case TCGA-VM-A8CF, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 44.7 years (16,334 days).
Specimen TCGA-VM-A8CF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a9e21751-9e50-4ac6-9805-19d90cb1b5f9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VM-A8CF-10A (Blood Derived Normal), aliquot TCGA-VM-A8CF-10A-01D-A367-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/96c5280f-9bdd-43ef-a7a8-ed1f798a697a

The open-access MAF lists 47 somatic variants for this specimen: 31 protein-altering or splice-affecting, 16 silent.
By variant classification: Missense Mutation 27, Silent 16, Frame Shift Del 2, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 29/66 reads (44%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 17/19 reads (89%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AP002512.3 | c.1097C>T p.P366L | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as COSV54408074, COSV99687833; called by muse, mutect2, varscan2
- ARHGAP1 | c.848G>C p.R283T | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100357901; called by muse, mutect2, varscan2
- COL21A1 | c.2636G>A p.G879E | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99778515; called by muse, mutect2, varscan2
- CRYAB | c.488G>A p.R163H | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.952); catalogued as rs782207078, COSV57051972; called by muse, mutect2, varscan2
- DCK | c.423G>T p.L141F | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs372497422; called by muse, mutect2, varscan2
- DUS4L-BCAP29 | c.386G>C p.C129S | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.149); catalogued as COSV50051640, COSV99143640; called by muse, mutect2, varscan2
- ENGASE | c.1921G>T p.A641S | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0.009); catalogued as COSV100285765; called by muse, mutect2, varscan2
- EPHA3 | c.986C>A p.P329Q | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100344880; called by muse, mutect2, varscan2
- FLG | c.11132T>C p.L3711P | Missense Mutation (SNP) | VAF 103/322 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.132); catalogued as COSV100911519; called by muse, mutect2, varscan2
- GABRA2 | c.166C>G p.R56G | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV100734183, COSV62913680; called by muse, mutect2, varscan2
- GCKR | c.493_495del p.K165del | In Frame Del (DEL) | VAF 9/58 reads (16%) | catalogued as rs780121754; called by pindel, varscan2
- GLRB | c.611-2A>G p.X204_splice | Splice Site (SNP) | VAF 39/85 reads (46%) | catalogued as COSV100029703, COSV52421740; called by muse, varscan2
- GNL3L | c.589G>A p.V197M | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.475); catalogued as rs1371914152, COSV100328331; called by muse, mutect2, varscan2
- GUCY1A2 | c.1720G>T p.V574F | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99974407; called by muse, mutect2, varscan2
- KIAA0232 | c.544T>C p.S182P | Missense Mutation (SNP) | VAF 46/109 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV56928545; called by muse, mutect2, varscan2
- MC5R | c.17A>G p.H6R | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.42); PolyPhen benign (0.015); catalogued as COSV100229021; called by muse, mutect2, varscan2
- MMP3 | c.649G>T p.A217S | Missense Mutation (SNP) | VAF 4/68 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100242794; called by muse, mutect2
- NCR1 | c.380C>T p.S127L | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.1); catalogued as rs142626797; called by muse, mutect2, varscan2
- PCDHB12 | c.2357A>G p.N786S | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.009); catalogued as rs782077784, COSV99507187; called by muse, mutect2, varscan2
- RGS13 | c.358T>A p.C120S | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.944); catalogued as rs761974239, COSV101232228; called by muse, mutect2, varscan2
- RIPK1 | c.1418G>A p.G473D | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV52527937, COSV52530478; called by muse, mutect2, varscan2
- SMARCA4 | c.3557C>T p.A1186V | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV60788639, COSV60811013; called by muse, mutect2, varscan2
- SNAPC3 | c.1129T>C p.C377R | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs770211819, COSV101055536; called by muse, mutect2, varscan2
- SYCE1 | c.388T>A p.L130M (on ENST00000343131 / NM_001143764.3; = p.L94M on NM_130784.3) | Missense Mutation (SNP) | VAF 33/177 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV100385819; called by muse, mutect2, varscan2
- TFEB | c.755A>G p.N252S | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100026167; called by muse, mutect2, varscan2
- USP9X | c.4576A>G p.M1526V | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.08); catalogued as COSV100199076; called by muse, mutect2, varscan2
- ATRX | c.1079_1082del p.I360Rfs*6 | Frame Shift Del (DEL) | VAF 34/105 reads (32%) | called by mutect2, pindel, varscan2
- CHST4 | c.634del p.R212Vfs*11 | Frame Shift Del (DEL) | VAF 4/31 reads (13%) | called by mutect2, varscan2
- DNAH17 | c.9416C>A p.A3139D | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ADAMTS17 | c.1200C>T p.D400= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as rs753792500, COSV51481242; called by muse, mutect2
- AGT | c.699G>T p.V233= | Silent (SNP) | VAF 10/75 reads (13%) | catalogued as rs1298710603, COSV100794335; called by muse, mutect2, varscan2
- ANGPT1 | c.681A>C p.T227= | Silent (SNP) | VAF 14/153 reads (9%) | catalogued as COSV52432203; called by muse, mutect2
- AP002512.3 | c.1098C>G p.P366= | Silent (SNP) | VAF 9/51 reads (18%) | catalogued as COSV54405380, COSV54406354; called by muse, mutect2, varscan2
- CD1E | c.654C>T p.G218= | Silent (SNP) | VAF 13/61 reads (21%) | catalogued as rs1465534015, COSV63770255; called by muse, mutect2, varscan2
- CHRNA1 | c.540T>C p.F180= (on ENST00000261007 / NM_001039523.3; = p.F155= on NM_000079.4) | Silent (SNP) | VAF 20/47 reads (43%) | catalogued as COSV99650381; called by muse, mutect2, varscan2
- FLNA | c.4738C>T p.L1580= | Silent (SNP) | VAF 3/12 reads (25%) | catalogued as COSV100774660; called by muse, mutect2
- FREM1 | c.6168G>A p.G2056= | Silent (SNP) | VAF 16/63 reads (25%) | catalogued as COSV101084354; called by muse, mutect2, varscan2
- IGKV1-6 | c.205C>T p.L69= | Silent (SNP) | VAF 10/226 reads (4%) | called by muse, mutect2
- KIR2DL1 | c.201C>T p.N67= | Silent (SNP) | VAF 8/192 reads (4%) | catalogued as rs144426670; called by muse, mutect2
- KRT34 | c.1086C>T p.N362= | Silent (SNP) | VAF 31/84 reads (37%) | catalogued as rs756379610, COSV67450509; called by muse, mutect2, varscan2
- LENG9 | c.585G>A p.P195= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as rs765760584, COSV100002790; called by muse, mutect2, varscan2
- OR5A1 | c.156C>T p.I52= | Silent (SNP) | VAF 17/129 reads (13%) | catalogued as COSV100118353; called by muse, mutect2, varscan2
- REST | c.1227A>G p.K409= | Silent (SNP) | VAF 30/170 reads (18%) | catalogued as COSV100470932; called by muse, mutect2, varscan2
- RP9 | c.654T>C p.S218= | Silent (SNP) | VAF 32/188 reads (17%) | catalogued as COSV99777960; called by muse, mutect2, varscan2
- TAFA4 | c.354G>C p.V118= | Silent (SNP) | VAF 58/139 reads (42%) | catalogued as rs757342099, COSV99806925; called by muse, mutect2, varscan2
